Somatic mutation profile of tumor specimen 0DSYED from CCDI case PBCIGF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 2.5 years (917 days).
Specimen 0DSYED: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dad86dec-4dfa-4c27-a2fd-62db08f931ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSYE6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff2a7b92-932b-4183-b11c-61513005ca2b

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Intron 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA2 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs533313019; called by muse, mutect2
- CD200R1 | c.364G>A p.V122M (on ENST00000471858 / NM_170780.3; = p.V145M on NM_138806.4) | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775414597; called by muse, mutect2
- COL22A1 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100278934, COSV57324822; called by muse, mutect2
- FHL1 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100600789; called by muse, mutect2, varscan2
- KCNA4 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 54/596 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV60251730; called by muse, mutect2
- NCOR2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 93/649 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs897767141; called by muse, mutect2, varscan2
- RP2 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1206639289; called by muse, mutect2, varscan2
- USP25 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 154/316 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774943583; called by muse, mutect2, varscan2
- ALG1 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 102/458 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ATRX | c.6898G>C p.V2300L | Missense Mutation (SNP) | VAF 41/461 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.107); called by muse, mutect2
- CLBA1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM186B | c.578T>A p.L193Q | Missense Mutation (SNP) | VAF 36/690 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- FHOD3 | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- HBE1 | c.7C>G p.H3D | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- OBSL1 | c.749G>C p.C250S | Missense Mutation (SNP) | VAF 21/582 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.186); called by muse, mutect2
- PAX5 | c.782C>G p.T261S | Missense Mutation (SNP) | VAF 137/513 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PCDH12 | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.012); called by muse, mutect2
- RBMX | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 137/334 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SART3 | c.1103A>C p.Y368S (on ENST00000228284; = p.Y350S on NM_014706.4) | Missense Mutation (SNP) | VAF 24/568 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEX11 | c.1935G>C p.L645F (on ENST00000344304; = p.L630F on NM_031276.3) | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2
- UGT2B11 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 43/584 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- UGT2B15 | c.1314-1G>T p.X438_splice | Splice Site (SNP) | VAF 18/257 reads (7%) | called by muse, mutect2
- ZC3H11A | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRG2 | c.435C>T p.G145= (on ENST00000379869 / NM_001079858.3; = p.G142= on NM_005756.4) | Silent (SNP) | VAF 38/253 reads (15%) | called by muse, mutect2, varscan2
- MGAT5B | c.555C>T p.Y185= | Silent (SNP) | VAF 107/385 reads (28%) | catalogued as rs772350405; called by muse, mutect2, varscan2
- OTC | c.324T>C p.P108= | Silent (SNP) | VAF 31/244 reads (13%) | called by mutect2, varscan2
- TJP3 | c.1833G>A p.V611= | Silent (SNP) | VAF 76/314 reads (24%) | called by muse, mutect2, varscan2
- SNED1 | c.3916+88G>T | Intron (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2, varscan2
- TBC1D32 | c.-24G>A | 5'UTR (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
